CCDI case PBBMII — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and ill-defined digestive organs.
https://portal.gdc.cancer.gov/cases/0648e0e0-3dc3-4a70-ab8d-560c8b2407a8

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Ewing sarcoma: ICD-O-3 morphology code: 9260/3; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 10.8 years (3,959 days).

Biospecimens (3 samples)
- Sample 0DCJR6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCJR8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DCJRA: Tissue type: Tumor; Specimen type: Solid Tissue.
